Gene-level copy-number profile of tumor specimen ALCH-B01Z-TTP1-A from ALCHEMIST case ALCH-B01Z, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.9 years (23,709 days).
Specimen ALCH-B01Z-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ae020625-01e3-47c9-909e-3b0b4c51e862.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B01Z-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,723 have no estimate.
https://portal.gdc.cancer.gov/files/08d0eb1e-3874-4178-8bef-4f0bdd53b3d3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 44; copy number 1: 23,547; copy number 2: 23,139; copy number 3: 12,164; copy number 4: 5; copy number 5: 1.

Homozygous deletions (total copy number 0; autosomes only): 42 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,492,300–2,557,031, 6 genes (within-gene range 0–1): AL139246.1, AL139246.4, PANK4, HES5, AL139246.5, TNFRSF14-AS1.
- chr3:126,988,594–127,037,392, 1 gene: PLXNA1.
- chr4:49,486,926–49,589,529, 12 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr9:42,183,659–42,569,353, 12 genes: SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2, FKBP4P6, SDR42E1P2, ATP5F1AP1, RAB28P3, RBPJP6, BX088651.4, BX088651.1.
- chr22:25,279,529–25,339,975, 4 genes: AL022332.1, AL022324.4, IGLL3P, AL022324.1.
- chr22:25,351,418–25,520,854, 7 genes: LRP5L, AL022324.3, AL008721.1, IGLVIVOR22-1, CRYBB2P1, MIR6817, AL008721.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:90,173,217–90,222,851, 1 gene, copy number 5 (within-gene range 1–5): LINC02193.

Autosomal genes at a single copy (total copy number 1): 20,717. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
